Somatic mutation profile of tumor specimen 0DN637 from CCDI case PBCBIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 14.5 years (5,292 days).
Specimen 0DN637: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddee6b2d-2fdb-470d-a970-4caf1aaa76c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN630 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147ffa0d-12d9-45b8-be1f-9666901a53f6

The open-access MAF lists 93 somatic variants for this specimen: 53 protein-altering or splice-affecting, 27 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 27, Intron 7, Nonsense Mutation 5, 3'UTR 3, Frame Shift Ins 2, 5'UTR 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 274/890 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by mutect2, varscan2
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 484/534 reads (91%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- CAPN9 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 202/520 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55234001; called by mutect2, varscan2
- CDC42 | c.194A>G p.D65G | Missense Mutation (SNP) | VAF 302/727 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV59663131; called by muse, mutect2, varscan2
- CYP4X1 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 381/999 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64151440; called by muse, mutect2, varscan2
- EHD4 | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs200735207, COSV55006051; called by muse, mutect2, varscan2
- EPB41L1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 239/1167 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs759706359; called by muse, mutect2, varscan2
- GRIK4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 519/1129 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs780640351, COSV70801363; called by muse, mutect2, varscan2
- GUF1 | c.1336-2A>G p.X446_splice | Splice Site (SNP) | VAF 258/609 reads (42%) | catalogued as rs1157566096, COSV55783711; called by muse, mutect2, varscan2
- HS3ST1 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 223/461 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs1184732309; called by muse, mutect2, varscan2
- IRS2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1370291086, COSV65476975; called by muse, mutect2, varscan2
- LGALS3BP | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 199/458 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs763776883; called by muse, mutect2, varscan2
- MUC16 | c.5501C>G p.T1834S | Missense Mutation (SNP) | VAF 163/504 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67479906; called by muse, mutect2, varscan2
- NOD2 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 247/626 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as rs201831159; called by muse, mutect2, varscan2
- OR11L1 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63313995; called by muse, mutect2, varscan2
- OR52N5 | c.520C>G p.R174G | Missense Mutation (SNP) | VAF 302/1240 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV57698769; called by muse, mutect2, varscan2
- PCDH11X | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 445/1044 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs373159801; called by muse, mutect2, varscan2
- SLA2 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 102/468 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs750957681; called by muse, mutect2, varscan2
- SPATA31A3 | c.544A>C p.S182R | Missense Mutation (SNP) | VAF 165/979 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1387334340; called by muse, mutect2, varscan2
- SPTAN1 | c.4117G>A p.G1373R | Missense Mutation (SNP) | VAF 422/965 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV63986208; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 195/435 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs559357120; called by muse, mutect2, varscan2
- ZNF251 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 397/1783 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs199876272; called by muse, mutect2, varscan2
- ABCA13 | c.4296C>A p.N1432K | Missense Mutation (SNP) | VAF 221/987 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AGAP3 | c.2358dup p.R787Afs*81 (on ENST00000622464; = p.R823Afs*81 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 148/687 reads (22%) | called by mutect2, varscan2
- APOBR | c.2143G>T p.E715* (on ENST00000431282; = p.E724* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 232/505 reads (46%) | called by muse, mutect2, varscan2
- AQR | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 362/825 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDR2L | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAAF4 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EFTUD2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 341/792 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171A2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 215/524 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FLG | c.11426C>A p.A3809E | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GCC2 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 448/1414 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GEN1 | c.1484C>A p.P495H | Missense Mutation (SNP) | VAF 304/754 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by mutect2, varscan2
- GRM2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 188/663 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGCS2 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 376/933 reads (40%) | called by muse, mutect2, varscan2
- KMT2D | c.15515dup p.E5173Rfs*26 | Frame Shift Ins (INS) | VAF 168/373 reads (45%) | called by mutect2, varscan2
- MALRD1 | c.970C>G p.H324D | Missense Mutation (SNP) | VAF 298/762 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MRTFA | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 280/627 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYH1 | c.5290A>C p.T1764P | Missense Mutation (SNP) | VAF 230/519 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MYL7 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 115/491 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- NEXMIF | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 163/420 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR9A2 | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 425/2163 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIKFYVE | c.4438C>A p.P1480T | Missense Mutation (SNP) | VAF 306/1034 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PPP1R9A | c.3147G>T p.K1049N | Missense Mutation (SNP) | VAF 426/1994 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by mutect2, varscan2
- PXDN | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 174/454 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RC3H2 | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 224/566 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SESN2 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 146/326 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SLC37A4 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 520/1229 reads (42%) | called by muse, mutect2, varscan2
- TFR2 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 244/995 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRPV5 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 161/777 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- TTC31 | c.1168A>T p.R390* | Nonsense Mutation (SNP) | VAF 143/485 reads (29%) | called by muse, mutect2, varscan2
- UBXN2A | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 332/775 reads (43%) | called by muse, mutect2, varscan2
- ZNF316 | c.589T>G p.L197V | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ATG9B | c.2187G>A p.G729= | Silent (SNP) | VAF 139/602 reads (23%) | catalogued as rs1383191611; called by muse, mutect2, varscan2
- AZU1 | c.648C>A p.S216= | Silent (SNP) | VAF 116/482 reads (24%) | called by muse, mutect2, varscan2
- C2CD3 | c.3009G>A p.E1003= | Silent (SNP) | VAF 226/1183 reads (19%) | catalogued as rs1320807765; called by muse, mutect2, varscan2
- CORO6 | c.1218G>A p.T406= | Silent (SNP) | VAF 173/415 reads (42%) | called by muse, mutect2, varscan2
- DLGAP2 | c.657C>T p.A219= | Silent (SNP) | VAF 153/696 reads (22%) | called by muse, varscan2
- IMPDH1 | c.576G>A p.T192= (on ENST00000470772 / NM_001142573.2; = p.T278= on NM_000883.4) | Silent (SNP) | VAF 251/1253 reads (20%) | catalogued as rs776020424; called by muse, mutect2, varscan2
- KCNJ10 | c.501G>A p.A167= | Silent (SNP) | VAF 269/581 reads (46%) | catalogued as rs200522826; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIDINS220 | c.3966G>A p.T1322= | Silent (SNP) | VAF 570/620 reads (92%) | catalogued as rs371285385; called by muse, varscan2
- KMT2D | c.16455C>G p.V5485= | Silent (SNP) | VAF 345/903 reads (38%) | catalogued as COSV56422364; called by muse, mutect2, varscan2
- MYBPC1 | c.576T>C p.G192= (on ENST00000550270 / NM_206820.2; = p.G217= on NM_002465.4) | Silent (SNP) | VAF 266/691 reads (38%) | catalogued as rs1281511989, COSV62253065; called by muse, mutect2, varscan2
- NLRP12 | c.114G>T p.L38= | Silent (SNP) | VAF 194/665 reads (29%) | catalogued as COSV60754705; called by muse, mutect2, varscan2
- OR2T2 | c.216C>A p.T72= | Silent (SNP) | VAF 186/1203 reads (15%) | catalogued as COSV100737706; called by muse, mutect2, varscan2
- OR2T35 | c.216C>A p.T72= | Silent (SNP) | VAF 48/54 reads (89%) | called by mutect2, varscan2
- PCDH8 | c.249G>A p.L83= | Silent (SNP) | VAF 230/516 reads (45%) | called by muse, mutect2, varscan2
- PGR | c.1149C>G p.P383= | Silent (SNP) | VAF 88/359 reads (25%) | catalogued as rs760317015, COSV54805186; called by muse, mutect2, varscan2
- RAB44 | c.939G>C p.R313= | Silent (SNP) | VAF 187/456 reads (41%) | called by muse, mutect2, varscan2
- RASA1 | c.1714C>T p.L572= | Silent (SNP) | VAF 321/770 reads (42%) | called by muse, mutect2, varscan2
- RAVER1 | c.1716C>T p.N572= (on ENST00000615032; = p.R699C on NM_133452.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 185/682 reads (27%) | called by muse, mutect2, varscan2
- SDR16C5 | c.291C>T p.C97= | Silent (SNP) | VAF 202/978 reads (21%) | catalogued as rs941002379, COSV58128491, COSV58128962; called by muse, mutect2, varscan2
- SETSIP | c.81A>G p.R27= | Silent (SNP) | VAF 393/1022 reads (38%) | called by muse, mutect2, varscan2
- SIK3 | c.3210G>T p.G1070= (on ENST00000445177 / NM_001366686.2; = p.G1028= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 173/971 reads (18%) | called by muse, mutect2, varscan2
- TGM2 | c.1146C>T p.G382= | Silent (SNP) | VAF 211/1029 reads (21%) | catalogued as rs541717032, COSV63932289; called by muse, mutect2, varscan2
- TMEM104 | c.954C>T p.Y318= | Silent (SNP) | VAF 204/516 reads (40%) | catalogued as rs375366362; called by muse, mutect2, varscan2
- TRPC4 | c.1632G>C p.T544= | Silent (SNP) | VAF 374/895 reads (42%) | catalogued as COSV58995782, COSV59019937; called by muse, mutect2, varscan2
- TRPM8 | c.2409G>A p.T803= | Silent (SNP) | VAF 353/1166 reads (30%) | catalogued as rs201342749, COSV100224437, COSV61223302; called by muse, mutect2, varscan2
- USP26 | c.2169T>C p.D723= | Silent (SNP) | VAF 349/788 reads (44%) | catalogued as rs1471876728; called by muse, mutect2, varscan2
- ZMYND12 | c.402G>T p.L134= | Silent (SNP) | VAF 441/997 reads (44%) | called by muse, mutect2, varscan2
- ACAN | c.7630+14C>T | Intron (SNP) | VAF 178/410 reads (43%) | catalogued as rs571354375; called by muse, mutect2, varscan2
- CCDC144A | c.739-56A>T | Intron (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- GNAI1 | c.118+21G>A | Intron (SNP) | VAF 84/365 reads (23%) | catalogued as rs954772934; called by muse, mutect2, varscan2
- NDST3 | c.981+52A>T | Intron (SNP) | VAF 245/513 reads (48%) | called by muse, mutect2, varscan2
- NEK10 | c.636+78G>A | Intron (SNP) | VAF 274/452 reads (61%) | catalogued as rs988447998; called by muse, mutect2, varscan2
- OR6C75 | chr12:55368799 del T | 3'Flank (DEL) | VAF 147/324 reads (45%) | called by mutect2, varscan2
- PSG1 | c.710-39G>C | Intron (SNP) | VAF 50/148 reads (34%) | catalogued as rs763686543; called by muse, mutect2, varscan2
- SHH | c.301-62G>A | Intron (SNP) | VAF 72/332 reads (22%) | called by muse, mutect2, varscan2
- SNX32 | c.*100A>G | 3'UTR (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- TIGD7 | c.-84A>T | 5'UTR (SNP) | VAF 70/139 reads (50%) | catalogued as rs1213085243; called by muse, mutect2, varscan2
- TMEM250 | c.-72G>A | 5'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- TRMT2B | c.*19G>T | 3'UTR (SNP) | VAF 327/836 reads (39%) | catalogued as COSV100105604; called by muse, mutect2, varscan2
- ZNF713 | c.*21A>T | 3'UTR (SNP) | VAF 126/540 reads (23%) | called by muse, mutect2, varscan2
